Somatic mutation profile of tumor specimen 0DKGYU from CCDI case PBBYIK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, metastatic, NOS; Tissue or organ of origin: Tail of pancreas; Age at diagnosis: 10.9 years (3,967 days).
Specimen 0DKGYU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56d77274-031c-4432-97b6-1c82e0197109.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKGXA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52daa36c-dae9-4ce8-941a-050e1b478d4e

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RANBP3 | c.883G>C p.A295P (on ENST00000340578 / NM_007322.3; = p.A290P on NM_003624.3) | Missense Mutation (SNP) | VAF 109/540 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV50380625; called by mutect2, varscan2
- TMPRSS2 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 86/983 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs775404304, COSV59825728; called by muse, mutect2
- ZNRF4 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 92/457 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as rs979351140, COSV55774691; called by muse, mutect2
- KDM2A | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 155/795 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- CNBD2 | c.954G>C p.L318= | Silent (SNP) | VAF 84/1150 reads (7%) | catalogued as COSV62586725; called by muse, mutect2
- DLG4 | c.1614C>T p.I538= (on ENST00000399506 / NM_001321075.3; = p.I581= on NM_001365.4) | Silent (SNP) | VAF 74/985 reads (8%) | called by muse, mutect2
- KDM2A | c.*3C>A | 3'UTR (SNP) | VAF 122/698 reads (17%) | called by muse, mutect2
- L3MBTL1 | c.951+79G>A | Intron (SNP) | VAF 15/146 reads (10%) | catalogued as rs977133095; called by muse, mutect2, varscan2
